Surgical pathology report (de-identified scan), TCGA case TCGA-NI-A8LF, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Roswell Park, specimen TCGA-NI-A8LF-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site Liver
C22D

9/24/13

SPECIMENS:

- A. LEFT LATERAL HEPATIC SEGMENTECTOMY
- B. NEW MEDIAL MARGIN

SPECIMEN(S):

- A. LEFT LATERAL HEPATIC SEGMENTECTOMY
- B. NEW MEDIAL MARGIN

DIAGNOSIS:

- A. LIVER, LEFT LOBE, LEFT LATERAL SEGMENTECTOMY:
- MODERATELY TO POORLY DIFFERENTIATED HEPATOCELLULAR CARCINOMA, 6.5 X 6 X 4.6 CM
- PREDOMINANTLY SOLID WITH FOCAL TRABECULAR GROWTH PATTERNS
- TUMOR IS FOCALLY 1 MM TO THE RESECTION EDGE (SEE PART B AND SYNOPTIC REPORT FOR FINAL MARGIN STATUS)
- B. LIVER, NEW MEDIAL MARGIN, EXCISION:
- LIVER PARENCHYMA, NEGATIVE FOR CARCINOMA

SYNOPTIC REPORT - LIVER NEOPLASM

Specimens Involved

Specimens: A: LEFT LATERAL HEPATIC SEGMENTECTOMY

B: NEW MEDIAL MARGIN

Specimen Type: Left lateral segmentectomy

Focality: Solitary

Tumor Size: Greatest dimension: 6.5cm

Additional dimensions: 6cm x 4.6cm

WHO Classification

Hepatocellular carcinoma (liver cell carcinoma) 8170/3

Histologic Type: Hepatocellular carcinoma

Histologic Grade: G3: Poorly differentiated

Extent of Invasion: Confined to the liver

Margins: Parenchymal

Margins uninvolved by invasive carcinoma

Specific margin: Medial

Angiolymphatic Invasion: Indeterminate

Carcinoma In Situ: Absent

Perineural Invasion: Absent

Additional Findings: None identified

Lymph Nodes: None sampled

Extranodal Extensions: Absent

Pathological Staging (pTNM): pT 1 N X M X

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

GROSS DESCRIPTION:

A. LEFT LATERAL HEPATIC SEGMENTECTOMY

Received fresh and subsequently fixed in formalin labeled with the patient's identification and designated "left lateral hepatic segmentectomy" it is a portion of previously inked (black at resection margin) and procured partial hepatectomy specimen weighing 315 g and measuring 15 x 9 x 6.5 cm. The specimen is sectioned to show an encapsulated, soft, dark yellow/tan lobulated mass with hemorrhagic center measuring 6.5 x 6 x 4.6 cm, located approximately 0.1 cm from the surgical resection margin. The remainder of the specimen shows pale red/tan, focally congested liver parenchyma. No additional lesions or nodules are grossly appreciated. Gross photograph is taken. Representative sections are submitted:

A1-A3: Mass, resection margin

[page 2 of 2]
A4-A6: Mass, capsule

A7-A9: Additional sections mass, central portion

A10: Uninvolved liver parenchyma

B. NEW MEDIAL MARGIN

Received fresh labeled with the patient's identification and designated "new medial margin" is an oriented portion of liver tissue (multiple staples) weighing 48 g and measuring 9.3 x 4.3 x 3.2 cm. A suture marks the old posterior medial margin, inked black, the remainder of the specimen inked blue. The specimen is sectioned to show unremarkable red-tan congested liver parenchyma. No lesions or nodules are grossly appreciated. Representatively submitted, B1-B3.

CLINICAL HISTORY:

None Given

PRE-OPERATIVE DIAGNOSIS:

Liver mass, suspect HCC

FROZEN SECTION INTRAOPERATIVE REPORT:

Part A: Left lateral hepatic segmentectomy, gross examination: 6 x 6 x 4.6 cm tumor mass located 0.1 cm from resection margin

Diagnosis given to Dr.

Gross Dictation:

Microscopic/Diagnostic Dictation: Pathologist,

Final Review Pathologist

Final: Pathologist,

HPVAA Discrepancy		✓

Source: NCI Genomic Data Commons file a4b77f24-6d5b-4c3c-899a-939326208435 (TCGA-NI-A8LF.5B4751DF-719F-4F2B-8D27-D69E480F6881.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).